Surgical pathology report (de-identified scan), TCGA case TCGA-37-4129, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Cureline, specimen TCGA-37-4129-01A (Primary Tumor).

[page 1 of 4]
Index							
1							

[page 2 of 4]
TCGA-37-4129

	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container
	Lung	Primary	Tumor	Tissue	OCT	block	1	n/a
	Blood	n/a	Normal	Blood	frozen	tube	1	n/a

[page 3 of 4]
TCGA-37-4129

Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type
n/a	surgery	Malignant carcinoid	2	2	0	0	none
n/a	blood draw	n/a	n/a	n/a	n/a	n/a	none

[page 4 of 4]
Component of treatment (Chemo / Horm Th Details)	Tumor cell %
n/a	70
n/a	n/a

Source: NCI Genomic Data Commons file 67557c1d-5c06-4ef4-a0da-b465d3f0f39a (TCGA-37-4129.609DB8AB-D13D-46EC-A247-A638DA93E35B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).